Somatic mutation profile of tumor specimen TCGA-BG-A0MG-01A (aliquot TCGA-BG-A0MG-01A-21D-A10B-09) from TCGA case TCGA-BG-A0MG, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G1; Age at diagnosis: 73.8 years (26,957 days).
Specimen TCGA-BG-A0MG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4c7566a7-eaa7-43df-94bd-f7e8f7713b44.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BG-A0MG-10A (Blood Derived Normal), aliquot TCGA-BG-A0MG-10A-01D-A10B-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/da64f650-a22a-4aec-8f97-7e2a700b12cf

The open-access MAF lists 122 somatic variants for this specimen: 93 protein-altering or splice-affecting, 29 silent.
By variant classification: Missense Mutation 72, Silent 29, Nonsense Mutation 9, Frame Shift Del 6, In Frame Del 2, Frame Shift Ins 2, Splice Region 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 35/99 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1393_1401del p.R465_Y467del (on ENST00000521381 / NM_181523.3; = p.R195_Y197del on NM_181504.4) | In Frame Del (DEL) | VAF 53/170 reads (31%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- ADAMTS12 | c.4063G>A p.D1355N | Missense Mutation (SNP) | VAF 57/131 reads (44%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.864); catalogued as COSV100711651, COSV61257949, COSV61268012; called by muse, mutect2, varscan2
- AGRN | c.2165G>T p.G722V | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV65068340, COSV65069601; called by muse, mutect2, varscan2
- AGTRAP | c.332G>A p.R111Q | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.072); catalogued as rs750218314, COSV58668477; called by muse, mutect2, varscan2
- ANKRD30A | c.1175C>G p.P392R (on ENST00000611781; = p.P336R on NM_052997.2) | Missense Mutation (SNP) | VAF 87/313 reads (28%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.804); catalogued as COSV100652614, COSV64606434, COSV64620314; called by muse, mutect2, varscan2
- AP3S1 | c.197G>C p.R66T | Missense Mutation (SNP) | VAF 88/536 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57473704; called by muse, mutect2
- AQP12A | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 51/119 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs774372497, COSV61836788; called by muse, mutect2, varscan2
- ARID1A | c.3972C>A p.Y1324* | Nonsense Mutation (SNP) | VAF 83/216 reads (38%) | catalogued as rs377622327, COSV61372705; called by muse, mutect2, varscan2
- ARID4A | c.1169G>A p.R390K | Missense Mutation (SNP) | VAF 46/135 reads (34%) | SIFT tolerated (0.85); PolyPhen benign (0.362); catalogued as COSV62162596, COSV62167066; called by muse, mutect2, varscan2
- CCDC9B | c.1389G>A p.W463* | Nonsense Mutation (SNP) | VAF 12/38 reads (32%) | catalogued as COSV66874984, COSV66875181; called by muse, mutect2, varscan2
- CD300A | c.422C>T p.T141I | Missense Mutation (SNP) | VAF 59/157 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV60409700; called by muse, mutect2, varscan2
- CELSR3 | c.7446G>C p.Q2482H | Missense Mutation (SNP) | VAF 49/126 reads (39%) | SIFT tolerated (0.56); PolyPhen benign (0.261); catalogued as COSV99374340; called by muse, mutect2, varscan2
- CHD4 | c.2885G>A p.R962H (on ENST00000357008 / NM_001363606.2; = p.R975H on NM_001273.5) | Missense Mutation (SNP) | VAF 117/211 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58896611, COSV58901386; called by muse, mutect2, varscan2
- CHST10 | c.584_585del p.L195Hfs*5 | Frame Shift Del (DEL) | VAF 75/228 reads (33%) | catalogued as COSV51804574; called by mutect2, pindel, varscan2
- COL15A1 | c.4108G>A p.A1370T | Missense Mutation (SNP) | VAF 62/155 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.187); catalogued as COSV66642242; called by muse, mutect2, varscan2
- CPAMD8 | c.1580G>A p.C527Y (on ENST00000651564; = p.C480Y on NM_015692.5) | Missense Mutation (SNP) | VAF 94/247 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52232365; called by muse, mutect2, varscan2
- CSMD3 | c.3473G>A p.R1158H (on ENST00000297405 / NM_001363185.1; = p.R1054H on NM_052900.3) | Missense Mutation (SNP) | VAF 51/147 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756700595, COSV52095387; called by muse, mutect2, varscan2
- DGKA | c.1046A>G p.K349R | Missense Mutation (SNP) | VAF 160/518 reads (31%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV59385006; called by muse, mutect2, varscan2
- DNAAF5 | c.2372A>G p.Y791C | Missense Mutation (SNP) | VAF 53/367 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.166); catalogued as rs774146132, COSV52415153; called by muse, mutect2, varscan2
- DNAH7 | c.1123C>G p.L375V | Missense Mutation (SNP) | VAF 71/161 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.708); catalogued as COSV56756266, COSV56757053; called by muse, mutect2, varscan2
- DR1 | c.223C>T p.L75= | Splice Region (SNP) | VAF 10/300 reads (3%) | catalogued as COSV64725349; called by muse, mutect2
- ELAVL1 | c.613C>T p.R205* | Nonsense Mutation (SNP) | VAF 136/369 reads (37%) | catalogued as COSV60966012; called by muse, mutect2, varscan2
- EML1 | c.2275G>A p.D759N | Missense Mutation (SNP) | VAF 118/296 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.317); catalogued as rs778393782, COSV51742534; called by muse, mutect2, varscan2
- EP300 | c.5014G>T p.E1672* | Nonsense Mutation (SNP) | VAF 41/103 reads (40%) | catalogued as COSV54328881; called by muse, mutect2, varscan2
- EXOC3L4 | c.1262C>T p.P421L | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.45); catalogued as rs1438956673, COSV66295361; called by muse, mutect2, varscan2
- FAM24A | c.161dup p.N54Kfs*30 | Frame Shift Ins (INS) | VAF 109/478 reads (23%) | catalogued as rs779387808; called by mutect2, pindel, varscan2
- FAT1 | c.8649C>G p.Y2883* | Nonsense Mutation (SNP) | VAF 147/427 reads (34%) | catalogued as COSV71672822; called by muse, mutect2, varscan2
- FAT4 | c.11341G>A p.V3781I | Missense Mutation (SNP) | VAF 48/105 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.229); catalogued as rs764537596, COSV58675771; called by muse, mutect2, varscan2
- FGF9 | c.410G>T p.R137I | Missense Mutation (SNP) | VAF 76/167 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); catalogued as COSV66644252; called by muse, mutect2, varscan2
- FNDC3B | c.1680C>G p.S560R | Missense Mutation (SNP) | VAF 20/400 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61039106; called by muse, mutect2
- GCN1 | c.5662G>A p.G1888R | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56105155; called by muse, mutect2, varscan2
- GDF11 | c.446C>T p.T149M | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.652); catalogued as rs1458262102, COSV57689405; called by muse, mutect2, varscan2
- GPC3 | c.76C>A p.P26T | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.481); catalogued as COSV63660689; called by muse, mutect2, varscan2
- GPR12 | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 46/96 reads (48%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as rs1407307715, COSV67344146; called by muse, mutect2, varscan2
- GPRASP1 | c.3935A>T p.E1312V | Missense Mutation (SNP) | VAF 79/170 reads (46%) | SIFT tolerated (0.23); PolyPhen benign (0.274); catalogued as COSV64355063; called by muse, mutect2, varscan2
- GRM6 | c.570C>A p.F190L | Missense Mutation (SNP) | VAF 45/144 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV51436492; called by muse, mutect2, varscan2
- GRN | c.869G>T p.C290F | Missense Mutation (SNP) | VAF 67/204 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50006566; called by muse, mutect2, varscan2
- IL2RG | c.857C>A p.T286K | Missense Mutation (SNP) | VAF 161/385 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.071); catalogued as COSV52147626; called by muse, mutect2, varscan2
- JPH2 | c.1829G>A p.R610Q | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs925491624, COSV65902347; called by muse, mutect2, varscan2
- LAMP1 | c.337G>A p.V113I | Missense Mutation (SNP) | VAF 29/399 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374537669; called by muse, mutect2
- LRRIQ4 | c.391A>T p.K131* | Nonsense Mutation (SNP) | VAF 95/128 reads (74%) | catalogued as COSV61618849; called by muse, mutect2, varscan2
- MAGEC3 | c.1117G>A p.G373R | Missense Mutation (SNP) | VAF 29/134 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV53577482; called by muse, mutect2, varscan2
- MAPKAPK5 | c.437A>G p.H146R | Missense Mutation (SNP) | VAF 118/490 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV73411030; called by muse, mutect2, varscan2
- MDFIC | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 58/359 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs147614154; called by muse, mutect2, varscan2
- MTA1 | c.1906del p.R636Gfs*13 | Frame Shift Del (DEL) | VAF 20/49 reads (41%) | catalogued as COSV58760788; called by mutect2, varscan2
- MYH1 | c.5702G>A p.R1901H | Missense Mutation (SNP) | VAF 133/398 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs749613856, COSV56845196; called by muse, mutect2, varscan2
- NAV2 | c.4319C>A p.S1440Y (on ENST00000396087 / NM_001244963.2; = p.S1417Y on NM_145117.5) | Missense Mutation (SNP) | VAF 48/128 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60657411, COSV60666851; called by muse, mutect2, varscan2
- NAV3 | c.3419G>A p.R1140H | Missense Mutation (SNP) | VAF 64/266 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1464051201, COSV57067858, COSV99897044; called by muse, mutect2, varscan2
- NECTIN1 | c.605A>G p.N202S | Missense Mutation (SNP) | VAF 131/394 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.571); catalogued as rs143539245; called by muse, mutect2, varscan2
- NFASC | c.1550A>G p.E517G (on ENST00000339876 / NM_001378329.1; = p.E528G on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 102/256 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as COSV58361433; called by muse, mutect2, varscan2
- NRK | c.3013G>A p.G1005S | Missense Mutation (SNP) | VAF 38/135 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.021); catalogued as COSV54592088; called by muse, mutect2, varscan2
- OGFOD3 | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 82/191 reads (43%) | SIFT tolerated (0.51); PolyPhen benign (0.006); catalogued as rs776865897, COSV57339731; called by muse, mutect2, varscan2
- OR10J3 | c.430C>A p.Q144K | Missense Mutation (SNP) | VAF 48/120 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.081); catalogued as COSV59953746, COSV59953847; called by muse, mutect2, varscan2
- PBDC1 | c.42G>T p.E14D | Missense Mutation (SNP) | VAF 79/589 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV64895653; called by muse, mutect2, varscan2
- PCDH17 | c.3194C>G p.A1065G | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.05); catalogued as COSV64972746; called by muse, mutect2, varscan2
- PCDHA12 | c.1120G>A p.V374M | Missense Mutation (SNP) | VAF 76/192 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as COSV56485055; called by muse, mutect2, varscan2
- PCDHA2 | c.596C>T p.S199L | Missense Mutation (SNP) | VAF 179/426 reads (42%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.071); catalogued as COSV65365653; called by muse, mutect2, varscan2
- PIK3R1 | c.2153T>C p.V718A (on ENST00000521381 / NM_181523.3; = p.V448A on NM_181504.4) | Missense Mutation (SNP) | VAF 93/237 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.751); catalogued as COSV57126254; called by muse, mutect2, varscan2
- PRPF40B | c.929G>A p.R310H (on ENST00000380281; = p.R304H on NM_012272.3) | Missense Mutation (SNP) | VAF 56/187 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs776994704, COSV56058370, COSV56059670; called by muse, mutect2, varscan2
- PTEN | c.1026G>T p.K342N | Missense Mutation (SNP) | VAF 106/119 reads (89%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as CM132269, COSV100911310, COSV64292596, COSV64307072; called by muse, mutect2, varscan2
- RASGRF1 | c.887T>C p.I296T | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101369715; called by muse, mutect2
- RASIP1 | c.1099G>A p.D367N | Missense Mutation (SNP) | VAF 53/131 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); catalogued as COSV55803393; called by muse, mutect2, varscan2
- RBM10 | c.556C>T p.R186* | Nonsense Mutation (SNP) | VAF 81/201 reads (40%) | catalogued as COSV61308292; called by muse, mutect2, varscan2
- RIC3 | c.211C>T p.H71Y | Missense Mutation (SNP) | VAF 26/318 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as COSV58300974; called by muse, mutect2
- RNF145 | c.1969G>A p.A657T (on ENST00000424310 / NM_001199383.2; = p.A685T on NM_144726.2) | Missense Mutation (SNP) | VAF 92/209 reads (44%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as COSV50864881, COSV99193462; called by muse, mutect2, varscan2
- SCLT1 | c.1745C>T p.A582V | Missense Mutation (SNP) | VAF 174/481 reads (36%) | SIFT tolerated (0.97); PolyPhen benign (0.001); catalogued as rs138724704; called by muse, mutect2, varscan2
- SECISBP2L | c.2988G>T p.E996D (on ENST00000559471 / NM_001193489.2; = p.E951D on NM_014701.4) | Missense Mutation (SNP) | VAF 12/212 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV55933429; called by muse, mutect2
- SLIT2 | c.1477C>T p.R493* | Nonsense Mutation (SNP) | VAF 93/211 reads (44%) | catalogued as COSV56564836; called by muse, mutect2, varscan2
- SMARCA4 | c.2713C>T p.R905C | Missense Mutation (SNP) | VAF 50/114 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs1555778721, COSV60789644, COSV60792364; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SNTG2 | c.574G>A p.G192R | Missense Mutation (SNP) | VAF 73/315 reads (23%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs145266598, COSV57972720; called by muse, mutect2, varscan2
- SNX32 | c.608T>C p.V203A | Missense Mutation (SNP) | VAF 61/146 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.084); catalogued as COSV57449099; called by muse, mutect2, varscan2
- SOD1 | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 24/810 reads (3%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.976); catalogued as rs1568810660, CM034918, COSV54255731; ClinVar: uncertain significance; called by muse, mutect2
- ST8SIA6 | c.604A>G p.T202A | Missense Mutation (SNP) | VAF 103/380 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66466821; called by muse, mutect2, varscan2
- TAF1 | c.1620A>T p.E540D (on ENST00000373790 / NM_138923.4; = p.E561D on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/386 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0.017); catalogued as COSV52109237; called by muse, mutect2
- TBC1D26 | c.623G>T p.W208L | Missense Mutation (SNP) | VAF 100/275 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.539); catalogued as COSV68608934; called by muse, mutect2, varscan2
- TENT4B | c.859A>G p.T287A (on ENST00000561678 / NM_001365323.2; = p.T272A on NM_001040284.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 159/332 reads (48%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.748); catalogued as COSV62546740; called by muse, mutect2, varscan2
- TNKS1BP1 | c.427C>T p.R143W | Missense Mutation (SNP) | VAF 56/157 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1448251223, COSV64100377; called by muse, mutect2, varscan2
- TNRC6A | c.2714A>G p.N905S | Missense Mutation (SNP) | VAF 49/117 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV59362266; called by muse, mutect2, varscan2
- TRIM65 | c.1226T>C p.L409P | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.478); catalogued as COSV53932532; called by muse, mutect2, varscan2
- TXNIP | c.1164_1166del p.N389del | In Frame Del (DEL) | VAF 107/295 reads (36%) | catalogued as rs1553765789; called by pindel, varscan2
- UFL1 | c.455T>G p.F152C | Missense Mutation (SNP) | VAF 23/484 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65149545; called by muse, mutect2
- UGT2B28 | c.1572G>T p.K524N | Missense Mutation (SNP) | VAF 154/454 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.25); catalogued as COSV100159016, COSV59431134; called by muse, mutect2, varscan2
- UHRF1BP1L | c.4393T>A p.*1465Kext*10 | Nonstop Mutation (SNP) | VAF 62/239 reads (26%) | catalogued as COSV54435503; called by muse, mutect2, varscan2
- ULK2 | c.2105C>T p.P702L | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as rs1022680609, COSV64444719; called by muse, mutect2, varscan2
- WDR36 | c.106A>T p.K36* | Nonsense Mutation (SNP) | VAF 10/78 reads (13%) | catalogued as COSV72411062, COSV72411539; called by muse, mutect2
- ZNF606 | c.1714G>C p.E572Q | Missense Mutation (SNP) | VAF 33/180 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.226); catalogued as COSV58705353; called by muse, mutect2, varscan2
- GSK3B | c.1020dup p.D341* (on ENST00000264235 / NM_001146156.2; = p.D354* on NM_002093.4) | Frame Shift Ins (INS) | VAF 269/456 reads (59%) | called by mutect2, pindel, varscan2
- ICE2 | c.349_350del p.K117Dfs*12 | Frame Shift Del (DEL) | VAF 75/245 reads (31%) | called by mutect2, pindel, varscan2
- NBEAL2 | c.3527_3540del p.P1176Qfs*10 | Frame Shift Del (DEL) | VAF 17/82 reads (21%) | called by mutect2, pindel, varscan2
- NDUFB6 | c.29T>G p.L10R | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- SMARCA1 | c.1497_1500del p.K499Nfs*12 | Frame Shift Del (DEL) | VAF 65/191 reads (34%) | called by mutect2, pindel, varscan2
- UBE3A | c.1132del p.V378Ffs*6 | Frame Shift Del (DEL) | VAF 70/194 reads (36%) | called by mutect2, pindel, varscan2
- AHRR | c.276G>A p.A92= | Silent (SNP) | VAF 21/85 reads (25%) | catalogued as rs757564795, COSV57083882; called by muse, mutect2, varscan2
- ATP13A5 | c.1806G>A p.S602= | Silent (SNP) | VAF 87/129 reads (67%) | catalogued as rs138029126, COSV60867063; called by muse, mutect2, varscan2
- ATP7B | c.3489C>T p.S1163= | Silent (SNP) | VAF 149/367 reads (41%) | catalogued as rs193922106; ClinVar: likely benign; called by muse, mutect2, varscan2
- CCT8L2 | c.585C>T p.D195= | Silent (SNP) | VAF 56/162 reads (35%) | catalogued as rs745781591, COSV63461750; called by muse, mutect2, varscan2
- CDH8 | c.1368A>G p.R456= | Silent (SNP) | VAF 94/263 reads (36%) | catalogued as COSV54854772; called by muse, mutect2, varscan2
- COG5 | c.1113G>A p.S371= | Silent (SNP) | VAF 15/125 reads (12%) | catalogued as rs768870825, COSV51745306; called by muse, mutect2, varscan2
- DBH | c.1716C>T p.R572= | Silent (SNP) | VAF 76/176 reads (43%) | catalogued as COSV67548880; called by muse, mutect2, varscan2
- DMD | c.978A>G p.E326= | Silent (SNP) | VAF 130/355 reads (37%) | catalogued as rs778154286, COSV55859809; called by muse, mutect2, varscan2
- DNAH2 | c.3288C>T p.H1096= | Silent (SNP) | VAF 211/520 reads (41%) | catalogued as rs201377977, COSV66717629, COSV66726095; called by muse, mutect2, varscan2
- DUSP4 | c.804C>T p.A268= | Silent (SNP) | VAF 10/19 reads (53%) | catalogued as rs146191698; called by muse, mutect2, varscan2
- EMC2 | c.753G>A p.K251= | Silent (SNP) | VAF 65/163 reads (40%) | catalogued as COSV55208504; called by muse, mutect2, varscan2
- GJA3 | c.447C>T p.Y149= | Silent (SNP) | VAF 36/71 reads (51%) | catalogued as COSV53834573; called by muse, mutect2, varscan2
- HBE1 | c.171C>A p.G57= | Silent (SNP) | VAF 69/178 reads (39%) | catalogued as COSV53079697; called by muse, mutect2, varscan2
- HSPA13 | c.984G>T p.L328= | Silent (SNP) | VAF 84/213 reads (39%) | catalogued as COSV53464841; called by muse, mutect2, varscan2
- IZUMO1 | c.669G>A p.V223= | Silent (SNP) | VAF 49/116 reads (42%) | catalogued as COSV55803405; called by muse, mutect2, varscan2
- LIG3 | c.2022G>A p.L674= | Silent (SNP) | VAF 33/129 reads (26%) | catalogued as COSV52006461; called by muse, mutect2, varscan2
- MDGA1 | c.2523C>T p.Y841= | Silent (SNP) | VAF 62/169 reads (37%) | catalogued as rs565856885, COSV51793353; called by muse, mutect2, varscan2
- MRPS36 | c.9C>T p.G3= | Silent (SNP) | VAF 22/328 reads (7%) | catalogued as COSV56507661; called by muse, mutect2
- NOL10 | c.499C>A p.R167= | Silent (SNP) | VAF 97/251 reads (39%) | catalogued as COSV62038464; called by muse, mutect2, varscan2
- PCDHB7 | c.789C>T p.S263= | Silent (SNP) | VAF 91/244 reads (37%) | catalogued as COSV50757286; called by muse, mutect2, varscan2
- RTP5 | c.1695C>T p.P565= | Silent (SNP) | VAF 34/100 reads (34%) | catalogued as rs368583788, COSV100574782; called by muse, mutect2, varscan2
- SEC23IP | c.720G>C p.P240= | Silent (SNP) | VAF 31/260 reads (12%) | catalogued as COSV64830999; called by muse, mutect2, varscan2
- SRM | c.345C>T p.P115= | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as COSV65384505; called by muse, mutect2, varscan2
- TRIM2 | c.855C>T p.A285= (on ENST00000437508; = p.A312= on NM_015271.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 38/98 reads (39%) | catalogued as rs1217667637, COSV58631979; called by muse, mutect2, varscan2
- TRIM47 | c.1467C>T p.I489= | Silent (SNP) | VAF 72/156 reads (46%) | catalogued as rs776802544, COSV54667892; called by muse, mutect2, varscan2
- TSHR | c.1527G>T p.V509= | Silent (SNP) | VAF 468/1172 reads (40%) | catalogued as COSV53316331; called by muse, mutect2, varscan2
- TSHZ3 | c.1893G>A p.P631= | Silent (SNP) | VAF 38/84 reads (45%) | catalogued as rs202193828, COSV53666897; called by muse, mutect2, varscan2
- WNT4 | c.207C>T p.R69= | Silent (SNP) | VAF 82/212 reads (39%) | catalogued as rs768304494, COSV51602989; called by muse, mutect2, varscan2
- ZNF287 | c.1980C>T p.G660= | Silent (SNP) | VAF 24/441 reads (5%) | catalogued as rs149309490; called by muse, mutect2
